Gene-level copy-number profile of tumor specimen TCGA-MU-A5YI-01A from TCGA case TCGA-MU-A5YI, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IA1; Tumor grade: G2; Age at diagnosis: 60.0 years (21,927 days).
Specimen TCGA-MU-A5YI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.84f8bb9b-01d6-452b-a3e1-f658dd0b94d6.absolute_liftover.gene_level_copy_number.v36.tsv, workflow ABSOLUTE segment calls lifted over to GRCh38 (Affymetrix SNP 6.0); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 3,490 have no estimate.
https://portal.gdc.cancer.gov/files/4b7ea037-ba67-440d-8ba3-32174818eeda

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 14; copy number 1: 7,174; copy number 2: 46,252; copy number 3: 3,532; copy number 4: 80; copy number 5: 81.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-MU-A5YI-01A-11D-A32H-01): tumor purity 0.7, ploidy 1.92, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 14 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:29,797,652–31,228,847, 14 genes: MTND4LP9, RBMS3-AS1, AC025614.2, AC025614.1, U3, LINC01985, AC116035.1, TGFBR2, AC096921.1, AC096921.2, GADL1, MIR466, CNN2P6, RNA5SP127.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 81 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:19,817,391–19,967,259, 2 genes, copy number 5 (within-gene range 3–5): INTS10, LPL.
- chr20:31,404,845–33,443,763, 79 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 7,174. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
